Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A1GF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A1GF-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

150-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 1/31/11
lw

Diagnosis:

A: Lymph nodes, right peri-aortic, lymph node dissection

- No carcinoma identified in five lymph nodes (0/5)

B: Lymph node, left peri-aortic, lymph node dissection

- No carcinoma identified in four lymph nodes (0/4)

C: Uterus, cervix, bilateral ovaries and fallopian tubes, hysterectomy with bilateral salpingoophorectomy:

Location of tumor: Endometrium

Histologic type: Endometrioid adenocarcinoma

Histologic grade (FIGO): Grade 2

Extent of invasion: Tumor shows superficial invasion of myometrium

Myometrial invasion: Inner half

Depth: 2 mm Wall thickness: 19 mm Percent: 11%

Serosal involvement: Not identified

Lower uterine segment involvement: Not identified

Cervical involvement: Not identified

Adnexal involvement (see below): Not identified

Cervical/vaginal margin and distance: Free of carcinoma

Lymphovascular Space Invasion: Not identified

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 25

Other Pathologic findings:

[page 2 of 4]
Cervix: Endocervical polyp; chronic inflammation and squamous metaplasia

Endometrium: Submucosal leiomyoma

Myometrium: No diagnostic histopathologic change

Tumor estrogen receptor and progesterone receptor immunohistochemistry results:

Estrogen receptor: Greater than 90% of tumor cells show strong (3+/3) nuclear staining.

Progesterone receptor: Greater than 90% of tumor cells show strong (3+/3) nuclear staining.

AJCC Pathologic Stage: pT1b pN0 pMx

FIGO (2008 classification) Stage grouping: IA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right: Stromal hyperthecosis; surface fibrous adhesions

Ovary, left: Stromal hyperthecosis; surface epithelial inclusions

Fallopian tube, right: Aggregate of ectopic hilus cells noted (less than 1 mm in diameter)

Fallopian tube, left: Endometriosis

D: Lymph nodes, right pelvic, lymph node dissection

- No carcinoma identified in seven lymph nodes (0/7)

E: Lymph nodes, left pelvic, lymph node dissection

- No carcinoma identified in nine lymph nodes (0/9)

Clinical History:

with endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "right para-aortic nodes." Examination of the contents of this container reveals multiple yellow/tan soft tissue fragments that are fatty. Aggregate dimensions are 4.5 cm x 1.5 x 1.5 cm. This specimen is examined for lymph nodes. Lymph node candidates are submitted in blocks A1-A4. Fatty tissue is returned to the container.

Container B is additionally labeled "left para-aortic nodes." Examination of the contents of this container reveals a fatty soft tissue fragment measuring 3.4 x 1.2 x 1.2 cm. This tissue is examined for lymph nodes. Lymph node candidates are placed into blocks B1 and B2. Fatty tissue is returned to the container.

Container C is additionally labeled "uterus, cervix, bilateral tubes and ovaries."

[page 3 of 4]
Block Summary:

- C1 - anterior cervix
- C2 - anterior lower uterine segment
- C3 - anterior mid corpus
- C4 - anterior upper corpus
- C5 - posterior cervix
- C6 - posterior lower uterine segment
- C7 - posterior mid corpus
- C8 - posterior upper corpus
- C9 - right ovary
- C10 - right fallopian tube
- C11 - left ovary
- C12 - left fallopian tube
- C13 - cervical polyp
- C14 - small nodule in lower uterine segment

Container D is additionally labeled "right pelvic nodes." Examination of the contents of this container reveals one 4.5 cm x 2.5 x 2.0 cm fatty soft tissue fragment. This soft tissue fragment is examined for lymph nodes. One lymph node is bisected and submitted into block D1. One lymph node is bisected and submitted in block D2. One lymph node is bisected and placed into block D3. One lymph node is bisected and placed into block D4. Other candidate lymph nodes are placed into block D5. Fatty and supportive tissue is returned to the container.

Container E is additionally labeled "left pelvic nodes." Examination of the contents of this container reveals one tan fatty soft tissue fragment. This soft tissue fragment has dimensions of 5.5 x 4.0 x 1.5 cm. It is examined for lymph nodes. One lymph node is bisected and placed into blocks E1 and E2; one lymph node is bisected and placed into blocks E3 and E4; each half is further bisected into halves in each container. Therefore, all of the lymph node samples in blocks E3 and E4 are from the same lymph node. Another lymph node is placed into block E5. Remaining lymph node candidates are placed into blocks E6 and E7. Remaining fat and supportive tissue is returned to the container.

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

[page 4 of 4]
Adnexa: present bilaterally

Weight: 156.4 grams

Shape: cylindrical

Dimensions:

height: 10.3 cm

anterior to posterior width: 5.0 cm

breadth at fundus: 6.0 cm

Serosa: glossy, tan without lesions externally

Cervix:

length of endocervical canal: 3.0 cm

ectocervix: white/tan, glossy without lesions

endocervix: smooth, dilated, without mass lesions, tan

Endomyometrium:

length of endometrial cavity: 3.0 cm

width of endometrial cavity at fundus: 3.0 cm

tumor findings:

dimensions: 3.0 x 2.9 x 1.5 cm

appearance: white/tan and morcellated; irregular in shape and soft to palpation

location and extent: fundus; this tumor takes up most of the endometrial cavity

myometrial invasion: inner one-half

thickness of myometrial wall at deepest gross invasion: 1.5 cm

other findings or comments: none

Adnexa:

Right ovary:

dimensions: 2.9 x 2.1 x 0.7 cm

external surface: white, bosselated, without lesions

cut surface: white/tan without lesions

Right fallopian tube:

dimensions: 5.5 x 0.7 cm

other findings: none

Left ovary:

dimensions: 2.5 x 1.5 x 0.8 cm

external surface: white/tan, bosselated, irregular

cut surface: tan/white; On the center of the cut surface is a 0.6 cm white-colored area (represented in block C11).

Left fallopian tube:

dimensions: 3 x 0.6 cm

other findings: none

Lymph nodes:

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: no

Source: NCI Genomic Data Commons file 9a52e064-2c99-4f79-87bc-8ed4511ac970 (TCGA-EY-A1GF.0C63BAC2-FD3E-49CB-A352-0B1653B78BDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).